Somatic mutation profile of tumor specimen TCGA-QR-A6GU-01A (aliquot TCGA-QR-A6GU-01A-11D-A35D-08) from TCGA case TCGA-QR-A6GU, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 31.7 years (11,592 days).
Specimen TCGA-QR-A6GU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37bba699-fcf6-4bfa-9ec9-c153b633541e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6GU-10A (Blood Derived Normal), aliquot TCGA-QR-A6GU-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/764acd3a-efc3-4745-acdd-469b273ead3a

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAJC5G | c.126G>T p.L42F | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV56079646; called by muse, mutect2, varscan2
- IL18RAP | c.156G>T p.Q52H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1461108694; called by muse, mutect2, varscan2
- NAGK | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs559948418, COSV99730616; called by muse, mutect2
- CDK19 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 18/277 reads (6%) | called by muse, mutect2
- CHRM3 | c.1493T>G p.L498R | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IRX6 | c.31C>A p.R11S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MEF2A | c.282T>A p.N94K | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NRXN3 | c.1279G>A p.D427N (on ENST00000335750 / NM_001330195.2; = p.D54N on NM_004796.6) | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2
- SHOC1 | c.1895T>C p.L632P | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- SLC1A3 | c.232G>T p.V78F | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- SLC26A3 | c.282T>A p.F94L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- ZEB2 | c.1630A>G p.T544A | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZSWIM4 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2
- CPNE2 | c.792G>A p.E264= | Silent (SNP) | VAF 26/172 reads (15%) | catalogued as rs748386130; called by muse, mutect2, varscan2
